Somatic mutation profile of tumor specimen TCGA-5P-A9JZ-01A (aliquot TCGA-5P-A9JZ-01A-11D-A42J-10) from TCGA case TCGA-5P-A9JZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 51.7 years (18,885 days).
Specimen TCGA-5P-A9JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a56d340-a9e1-4e78-a1e1-62ecf1d5140d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9JZ-10A (Blood Derived Normal), aliquot TCGA-5P-A9JZ-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e32f3697-9fe4-481a-bd36-217c22b214ae

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 29, Silent 8, Frame Shift Del 4, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRAXAS2 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100045166; called by muse, mutect2, varscan2
- ATIC | c.1521G>T p.K507N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV99378272; called by muse, mutect2, varscan2
- C7orf33 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 71/109 reads (65%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as COSV100188957; called by muse, mutect2, varscan2
- C8A | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.253); catalogued as COSV100776684; called by muse, mutect2, varscan2
- CAPN3 | c.461G>C p.S154T | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1177741110, COSV100533555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDHR3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745946514, COSV100488941; called by muse, mutect2, varscan2
- CEP68 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as COSV99561344; called by muse, mutect2, varscan2
- CHST7 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99333156; called by muse, mutect2, varscan2
- CNTN2 | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100085310, COSV100085570; called by muse, mutect2, varscan2
- DPP7 | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV100857339, COSV100857439; called by muse, mutect2, varscan2
- DPP7 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV100857440; called by muse, mutect2, varscan2
- HERC2 | c.12328G>A p.G4110R | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs753700021, COSV55335945; called by muse, mutect2, varscan2
- MAP1A | c.3295G>C p.V1099L | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV100289357, COSV55811251; called by muse, mutect2
- MFSD3 | c.1001T>A p.L334Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100020876; called by muse, mutect2, varscan2
- MTSS1 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV100275774; called by muse, mutect2
- MTUS2 | c.2503G>T p.G835C | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99686751; called by muse, mutect2, varscan2
- MTUS2 | c.2504G>T p.G835V | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV99686752; called by muse, mutect2, varscan2
- OR10G7 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs779903828, COSV57869277; called by muse, mutect2
- PAQR7 | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100961740; called by muse, mutect2, varscan2
- PCF11 | c.1751A>G p.N584S | Missense Mutation (SNP) | VAF 121/296 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as COSV53528037, COSV53537357; called by muse, mutect2, varscan2
- PFAS | c.3359C>A p.A1120E | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119202; called by muse, mutect2, varscan2
- PPP1R13B | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV99162988; called by muse, mutect2, varscan2
- PTCH2 | c.899G>A p.G300E | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942292; called by muse, mutect2, varscan2
- PTPRH | c.1535G>A p.W512* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99671520; called by muse, mutect2, varscan2
- PURA | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495816; called by muse, mutect2, varscan2
- SEMA4A | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100740753; called by muse, mutect2, varscan2
- SORL1 | c.6511G>A p.A2171T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.757); catalogued as rs146742626; called by muse, mutect2, varscan2
- SPEG | c.4728A>G p.S1576= | Splice Region (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100405841; called by muse, mutect2, varscan2
- TM4SF5 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV99564854; called by muse, mutect2, varscan2
- TRMT44 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV101077862; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99692261; called by muse, mutect2, varscan2
- ATG2A | c.1939_1940dup p.P648Sfs*27 | Frame Shift Ins (INS) | VAF 33/89 reads (37%) | called by mutect2, pindel, varscan2
- CCDC89 | c.905_917del p.I302Tfs*20 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2*
- FAM71F1 | c.780del p.F260Lfs*10 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- SF3A1 | c.2223_2232del p.K741Nfs*112 | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- SMAP1 | c.970_971del p.M324Gfs*84 (on ENST00000370455 / NM_001044305.3; = p.M297Gfs*84 on NM_021940.5) | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- CC2D2A | c.1878T>C p.D626= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV101052976; called by muse, mutect2, varscan2
- DNAJC21 | c.1017G>A p.R339= | Silent (SNP) | VAF 200/541 reads (37%) | catalogued as COSV100331614; called by muse, mutect2, varscan2
- EGFR | c.825C>T p.Y275= | Silent (SNP) | VAF 87/304 reads (29%) | catalogued as COSV51803664; called by muse, mutect2, varscan2
- GPR50 | c.1146C>T p.A382= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs878989542, COSV99506780; called by muse, mutect2, varscan2
- ITGB1 | c.1989G>A p.Q663= | Silent (SNP) | VAF 185/480 reads (39%) | catalogued as COSV100172084, COSV100172088; called by muse, mutect2, varscan2
- MASP1 | c.99G>A p.S33= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as rs74784100; called by muse, mutect2, varscan2
- MCM6 | c.2169C>A p.I723= | Silent (SNP) | VAF 85/249 reads (34%) | catalogued as COSV51469301, COSV99919441; called by muse, mutect2, varscan2
- RNASEH2A | c.621C>A p.G207= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV99677433; called by muse, mutect2, varscan2
